CCDI case PBBZTT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3b1e565c-64c1-464c-8a01-b850905846aa

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 10.3 years (3,759 days).

Biospecimens (3 samples)
- Sample 0DLX4L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DLX5H: Tissue type: Tumor; Specimen type: Solid Tissue.
